Somatic mutation profile of tumor specimen TCGA-XU-A932-01A (aliquot TCGA-XU-A932-01A-11D-A423-09) from TCGA case TCGA-XU-A932, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 37.3 years (13,618 days).
Specimen TCGA-XU-A932-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfb7dbdc-abb5-4256-ac20-59fd876309e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A932-10A (Blood Derived Normal), aliquot TCGA-XU-A932-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28e34aaf-2780-4c0d-9a94-7f8416d14361

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZRANB1 | c.1444A>G p.K482E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV62841658; called by muse, mutect2
- PEX11B | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PLEKHB1 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2
- SCARB1 | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2
- NUP160 | c.1377A>G p.Q459= | Silent (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
